Surgical pathology report (de-identified scan), TCGA case TCGA-AR-A0TT, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Mayo, specimen TCGA-AR-A0TT-01A (Primary Tumor).

1CD-0-3

Carcinoma, infiltrating duct, NOS 8500/3
Site: breast, NOS C50.9

Breast, right, wide local excision: Infiltrating ductal carcinoma, Nottingham grade III (of III) [tubules 3/3, nuclei 3/3, mitoses 2/3; Nottingham score 8/9], forming a mass (2.3 x 1.9 x 1.8 cm) [AJCC pT2]. Ductal carcinoma in situ is absent. Angiolymphatic invasion is absent. The non-neoplastic breast parenchyma shows nonproliferative fibrocystic changes. All surgical margins are negative for tumor (minimum tumor free margin, 0.5 cm, deep margin).

Lymph nodes, right axillary sentinel Nos. 1A, 1B, 1C, 2A, 2B, and 2C, excision: Multiple (3 of 6) right axillary sentinel lymph nodes, all without blue dye, are positive for metastatic carcinoma.

Lymph nodes, right axillary, dissection: Multiple (2 of 13) right axillary lymph nodes are positive for metastatic carcinoma [AJCC pN2]. Extranodal extension is present.

Her-2/NEU has been ordered on paraffin-embedded tissue.

Source: NCI Genomic Data Commons file abe1c610-fc4c-401b-b1ab-b2be2367bde2 (TCGA-AR-A0TT.E9231B33-E1CE-4396-9F9E-03DBF049919A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).